TCGA case TCGA-IC-A6RE — Esophageal Carcinoma (TCGA-ESCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Esophagus; Tissue source site: University of Pittsburgh. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/64aa95b2-ccf7-4bfa-8d4f-98de09f03e71

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 59 years; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C15.5; Tissue or organ of origin: Lower third of esophagus; Site of resection or biopsy: Esophagus, NOS; Classification of tumor: primary; Age at diagnosis: 59.2 years (21,640 days); Year of diagnosis: 2013; Method of diagnosis: Biopsy; AJCC staging edition: 7th; AJCC pathologic T: T1; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 234 days; Cancer detection method: Symptomatic; Sites of involvement: Esophagus, Lower Third.
   Pathology details: Consistent pathology review: Yes; Lymph node involvement: Positive; Lymph nodes positive: 2; Lymph nodes tested: 38.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Epirubicin + Fluorouracil; Days to treatment start: 151 days.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 234 days; Disease response: With Tumor.
- Barretts esophagus goblet cells present: Yes; Timepoint: Prior to Diagnosis.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 102 kg; Height: 183 cm; BMI: 30.5.
- Timepoint category: Prior to Diagnosis; Comorbidities: Barrett's Esophagus / GERD; Risk factors: Barrett's Esophagus / GERD.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 40.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-IC-A6RE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 220 mg.
  Slide TCGA-IC-A6RE-01A-01-TS1: Section location: Top; Percent tumor cells: 30; Percent tumor nuclei: 65; Percent normal cells: 0; Percent necrosis: 4; Percent stromal cells: 66; Percent lymphocyte infiltration: 20; Percent monocyte infiltration: 3; Percent neutrophil infiltration: 2.
- Sample TCGA-IC-A6RE-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-IC-A6RE-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 80 mg.
  Slide TCGA-IC-A6RE-11A-01-TS1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 15; Percent necrosis: 0; Percent stromal cells: 85; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; Cancer procurement state province: Pennsylvania; Cancer procurement city: Piitsburgh; History neoadjuvant treatment: No; Tumor status: With tumor; Tobacco smoking history indicator: 2; Alcohol history documented: Yes; History reflux disease indicator: Yes; History barretts esophageal indicator: Yes-USA; New tumor event diagnosis indicator: No.
- Primary pathology: Esophageal tumor location centered: Distal; Histologic diagnosis: Esophagus Adenocarcinoma, NOS; Method initial path diagnosis: Endoscopic Biopsy; Lymph node sprd radiograph evidence: Yes; Lymph nodes examined: Yes.
- Primary pathology, Esophageal tumor involvement sites: Esophageal tumor location involved: Distal.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Response; New tumor event diagnosis indicator: No.
- Drug treatment 3: Pharmaceutical therapy drug name: 5FU.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 234 days; disease-specific survival: no event (censored), 234 days; disease-free interval: no event (censored), 234 days; progression-free interval: no event (censored), 234 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-IC-A6RE-01A-11D-A33D-01): tumor purity 0.54, ploidy 2.24, whole-genome doublings 0.
